Surgical pathology report (de-identified scan), TCGA case TCGA-MB-A5Y9, project TCGA-SARC (Sarcoma), tissue source site University of Minnesota, specimen TCGA-MB-A5Y9-01A (Primary Tumor).

[page 1 of 5]
Study Subject ID:

TSS ID:

Tumor ID:

Collected:

Received:

Reported:

path ICD-O-3
Histocytoma, fibrous malignant 8830/3
c6CF Sarcoma, undifferentiated
pleomorphic 8865/3
Site: Connective, subcutaneous and
other soft tissues of
R calf C49.2
JW 4/29/13

SPECIMEN(S):

Right posterior calf mass

FINAL DIAGNOSIS:

Soft tissue, right posterior calf mass, wide excision

- Pleomorphic sarcoma, with features of malignant fibrous

histiocytoma

- Tumor measures 6.8 cm in greatest dimension

- Tumor focally present at anterior/deep margin

- See microscopic for description and soft tissue sarcoma checklist

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

[page 2 of 5]
The patient is a year old male with a sarcoma of right calf.

Operative procedure: Excision of right calf sarcoma.

GROSS:

One specimen is received labeled with the patient's name and medical record number.

The specimen is designated "right posterior calf mass." The specimen consists of a 12 x 10.5 x 4.0 cm, 217 gram pink tan soft tissue fragment. The overlying ovoid skin measures 12.6 x 9.8 cm showing bulging mass. The specimen is oriented as follows: long double stitch at proximal margin (12:00), single stitch at lateral margin (3:00). The resection margins are inked black. Serial sectioning reveals a 6.8 x 6.0 x 3.4 cm circumscribed pink tan soft tissue tumor with multifocal area of necrosis and small focal area of cystic change. The tumor is 1.6 cm from the proximal margin, 1.4 cm from the distal margin, 2.5 cm from the lateral margin, 2.7 cm from the medial margin, 0.4 cm from posterior skin surface and 0.1 cm from anterior deep margin.

Representative tissue was procured for potential future studies. The specimen is photographed. Representative sections are submitted in fifteen cassettes.

Summary of Sections:

1 - proximal margin

2 - distal margin

[page 3 of 5]
3 - lateral margin

4 - medial margin

5 - posterior skin

6 - anterior/deep margin

7 through 15 - tumor

MICROSCOPIC:

Microscopic evaluation is performed.

The tumor in this case is similar to the prior biopsy. It has extensive areas of pleomorphic tumor, with markedly atypical tumor cells and numerous tumor giant cells. There are also more spindle cells, as well, and areas with foamy histiocytic cells. A minor component of the tumor is less cellular, with atypical spindle cells and an abundant inflammatory cell component. Other areas have myxoid appearance, In aggregate, as with the prior biopsy, we believe that this is best classified as a malignant fibrous histiocytoma. For additional details, see below.

SOFT TISSUE: Resection

Procedure : Wide excision

Tumor Site: Right calf

[page 4 of 5]
Tumor Size: Greatest dimension: 6.8 cm; additional dimensions: 6.0 x 3.4 cm

Macroscopic Extent of Tumor: Superficial and deep

Histologic Type: Malignant fibrous histiocyoma

Mitotic Rate 45 /10 high-power fields (HPF)

Necrosis: Present; extent: 5-10%

Histologic Grade (French Federation of Cancer Centers Sarcoma Group [FNCLCC]): Grade 3

Margins: Margin(s) positive for sarcoma; "anterior-deep" margin, focal

Lymph-Vascular Invasion Not identified

Pathologic Staging (pTNM) (Note J)

TNM Descriptors

Primary Tumor (pT)

pT2b: Tumor more than 5 cm in greatest dimension, deep tumor

[page 5 of 5]
Regional Lymph Nodes (pN)

pNX: Regional lymph nodes cannot be assessed

No nodes submitted or found

Distant Metastasis (M)

M0: Distant metastasis clinically absent

Source: NCI Genomic Data Commons file 0e368efa-9a12-4207-b14a-7a0a730c068c (TCGA-MB-A5Y9.0F4606DC-6E3F-414E-8488-EB0C8D87511C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).